Somatic mutation profile of tumor specimen TCGA-BP-4801-01A (aliquot TCGA-BP-4801-01A-02D-1421-08) from TCGA case TCGA-BP-4801, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.0 years (20,825 days).
Specimen TCGA-BP-4801-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d4d3d0e-8897-4394-8fbd-bf7e2c30c03f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4801-11A (Solid Tissue Normal), aliquot TCGA-BP-4801-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1b7e55b-cdef-49fb-9cfa-e87702863f9a

The open-access MAF lists 63 somatic variants for this specimen: 52 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Frame Shift Del 7, Nonsense Mutation 4, Splice Site 1, In Frame Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADA2 | c.826T>G p.F276V (on ENST00000262607; = p.F35V on NM_177405.3) | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52831742; called by muse, mutect2, varscan2
- ADAMTS13 | c.2861G>C p.R954P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.599); catalogued as COSV63021491; called by muse, varscan2
- AKNA | c.404A>T p.E135V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV56312994; called by muse, mutect2, varscan2
- AMPH | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV57740782, COSV57743647; called by muse, mutect2, varscan2
- ARHGAP10 | c.1275G>C p.K425N | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1366290918, COSV60600180; called by muse, mutect2, varscan2
- ASB16 | c.567G>A p.L189= | Splice Region (SNP) | VAF 12/60 reads (20%) | catalogued as COSV53235057; called by muse, mutect2, varscan2
- ATG2A | c.2247G>C p.W749C | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.85); catalogued as COSV65967056; called by muse, mutect2
- ATP2A2 | c.2800G>C p.G934R | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.776); catalogued as COSV57875508; called by muse, mutect2, varscan2
- ATP8B2 | c.2005G>A p.V669I (on ENST00000672630; = p.V636I on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59246415; called by muse, mutect2, varscan2
- BRCA2 | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV66454812; called by muse, mutect2, varscan2
- BRD1 | c.1878G>C p.E626D | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.461); catalogued as COSV53457887; called by muse, mutect2, varscan2
- BRINP3 | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 37/222 reads (17%) | catalogued as COSV100818702, COSV66515003; called by muse, mutect2, varscan2
- CRYGS | c.418T>A p.Y140N | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57192510; called by muse, mutect2, varscan2
- DST | c.2553G>T p.M851I (on ENST00000361203 / NM_001374722.1; = p.M525I on NM_001723.6) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55018166; called by muse, mutect2, varscan2
- FAM135B | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV52728853, COSV99425888; called by muse, mutect2, varscan2
- FES | c.548A>G p.H183R | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51577163; called by muse, mutect2, varscan2
- G6PD | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63703396; called by muse, mutect2, varscan2
- GPRC5B | c.753G>A p.M251I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56026803; called by muse, mutect2, varscan2
- H2AC12 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100804660, COSV63617092; called by muse, mutect2, varscan2
- HCFC2 | c.780del p.F260Lfs*30 | Frame Shift Del (DEL) | VAF 34/194 reads (18%) | catalogued as COSV57558613; called by mutect2, pindel
- IL21R | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61970757; called by muse, mutect2, varscan2
- IWS1 | c.947A>T p.E316V | Missense Mutation (SNP) | VAF 68/364 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); catalogued as COSV54868828; called by muse, varscan2
- IWS1 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 72/361 reads (20%) | catalogued as COSV54868855; called by muse, varscan2
- KIAA1755 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 91/347 reads (26%) | catalogued as COSV54073304, COSV54077048; called by muse, mutect2, varscan2
- LMAN1 | c.881A>G p.E294G | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV51827159; called by muse, mutect2, varscan2
- LRRC42 | c.1088T>A p.L363H | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59960988; called by muse, mutect2, varscan2
- MIS12 | c.392A>C p.E131A | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50147457; called by muse, mutect2, varscan2
- MRO | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as COSV56496268; called by muse, mutect2, varscan2
- NFXL1 | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 105/425 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV61198696, COSV61199216; called by muse, mutect2, varscan2
- PBRM1 | c.528+1G>T p.X176_splice | Splice Site (SNP) | VAF 94/306 reads (31%) | catalogued as COSV56275199, COSV56280015; called by mutect2, varscan2
- PCSK5 | c.350A>C p.D117A | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV65089795; called by muse, mutect2, varscan2
- PRMT8 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54214695; called by muse, mutect2, varscan2
- PSG6 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs186311462; called by muse, mutect2, varscan2
- PTPN4 | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 19/91 reads (21%) | catalogued as COSV55302335; called by muse, mutect2, varscan2
- RAB40B | c.156G>T p.K52N | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53916482, COSV99483681; called by muse, mutect2, varscan2
- RGS18 | c.434C>G p.T145S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV66508331; called by muse, mutect2, varscan2
- SHF | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV52050692; called by muse, mutect2, varscan2
- STIL | c.3054T>G p.N1018K | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.439); catalogued as COSV54550725; called by muse, mutect2, varscan2
- SYNGAP1 | c.3296A>G p.Y1099C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.84); catalogued as rs772814285, COSV53381899; called by muse, mutect2
- TIMM50 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.062); catalogued as rs1489372422; called by muse, mutect2
- TOP3A | c.2989del p.C997Vfs*11 | Frame Shift Del (DEL) | VAF 34/141 reads (24%) | catalogued as rs777850988; called by mutect2, pindel, varscan2
- TRAF3IP1 | c.157T>C p.Y53H | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64852963; called by muse, mutect2, varscan2
- TSR1 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV52158464; called by muse, mutect2, varscan2
- TTN | c.12258G>C p.L4086F (on ENST00000591111; = p.L4040F on NM_003319.4) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | catalogued as COSV60103987; called by muse, mutect2
- TUBA4A | c.1190T>G p.L397R | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as COSV50278449; called by muse, mutect2, varscan2
- WTAP | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV61610185; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7392_7394del p.D2465del | In Frame Del (DEL) | VAF 47/351 reads (13%) | called by mutect2, pindel, varscan2
- ATM | c.2655_2658del p.A886Kfs*12 | Frame Shift Del (DEL) | VAF 34/262 reads (13%) | called by pindel, varscan2
- CACNA1A | c.307_308del p.M103Dfs*20 | Frame Shift Del (DEL) | VAF 54/256 reads (21%) | called by pindel, varscan2
- DCT | c.1547_1548del p.T516Rfs*11 | Frame Shift Del (DEL) | VAF 28/181 reads (15%) | called by pindel, varscan2
- GIGYF2 | c.3121del p.I1041Lfs*9 | Frame Shift Del (DEL) | VAF 21/188 reads (11%) | called by mutect2, pindel, varscan2
- NCOA2 | c.1148del p.N383Ifs*4 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- COPE | c.657C>T p.L219= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs781700062, COSV53230727; called by muse, mutect2, varscan2
- DOCK8 | c.504G>A p.L168= | Silent (SNP) | VAF 55/234 reads (24%) | catalogued as COSV66634241; called by muse, mutect2, varscan2
- DSCAML1 | c.3480G>C p.L1160= (on ENST00000321322; = p.L1100= on NM_020693.4) | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs759604883, COSV58390066, COSV58391988; called by muse, mutect2, varscan2
- EDEM2 | c.1299T>G p.T433= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV63259559; called by muse, mutect2
- HTR7 | c.267G>C p.T89= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV53287357, COSV99520282; called by muse, mutect2, varscan2
- MRGPRD | c.588G>C p.L196= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV58423304; called by muse, mutect2, varscan2
- OSBPL7 | c.1299C>G p.T433= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV50109246; called by muse, mutect2
- PTPRB | c.249C>A p.I83= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV51734079, COSV51746963, COSV51748037; called by muse, mutect2, varscan2
- SAMD15 | c.1161C>T p.I387= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV53626532; called by muse, mutect2, varscan2
- UBA6 | c.180C>T p.A60= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs1156549382, COSV59177876; called by muse, mutect2, varscan2
- EWSR1 | c.975-1134C>A | Intron (SNP) | VAF 7/34 reads (21%) | catalogued as COSV58424190; called by muse, mutect2
